Somatic mutation profile of tumor specimen 0DWI1G from CCDI case PBCNTJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 12.2 years (4,450 days).
Specimen 0DWI1G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a6d8833-79d4-4291-8e13-426d566a7eee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWHZ6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87c84d8e-4fcc-4f3e-a326-b37114b32bee

The open-access MAF lists 81 somatic variants for this specimen: 57 protein-altering or splice-affecting, 12 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 12, 3'UTR 6, Intron 4, Nonsense Mutation 4, Frame Shift Ins 3, Splice Site 2, 5'UTR 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD8 | c.5607dup p.D1870Rfs*3 (on ENST00000646647 / NM_001170629.2; = p.D1591Rfs*3 on NM_020920.4) | Frame Shift Ins (INS) | VAF 76/189 reads (40%) | catalogued as rs774152851; ClinVar: pathogenic; called by mutect2, varscan2
- SLC7A9 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 137/274 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121908482, CM992221, COSV50089408; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLU | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 114/1006 reads (11%) | catalogued as COSV100324366; called by muse, mutect2, varscan2
- CORO7 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 50/425 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs561810989, COSV99228271; called by muse, mutect2, varscan2
- DPYSL4 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 110/229 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs751981237; called by muse, mutect2, varscan2
- EPHA5 | c.845G>C p.W282S | Missense Mutation (SNP) | VAF 367/986 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746257878; called by muse, mutect2, varscan2
- EPS8L3 | c.1768G>A p.G590R (on ENST00000361965 / NM_133181.4; = p.G560R on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/258 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV62609749; called by muse, mutect2, varscan2
- GRID2 | c.2882G>C p.R961P | Missense Mutation (SNP) | VAF 36/650 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.969); catalogued as COSV56288661; called by muse, mutect2
- JMJD7-PLA2G4B | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 125/260 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs752705085; called by muse, mutect2, varscan2
- LRCH3 | c.941A>G p.N314S | Missense Mutation (SNP) | VAF 225/946 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.872); catalogued as rs773418585, COSV58397383; called by muse, mutect2, varscan2
- MUC16 | c.9515G>T p.S3172I | Missense Mutation (SNP) | VAF 190/514 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.455); catalogued as rs1171410891; called by muse, mutect2, varscan2
- MYO1C | c.271C>T p.R91W (on ENST00000648651 / NM_001080779.2; = p.R56W on NM_033375.5) | Missense Mutation (SNP) | VAF 164/272 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs374801393; called by muse, mutect2, varscan2
- OR4C12 | c.625T>G p.F209V | Missense Mutation (SNP) | VAF 36/980 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); catalogued as rs369617851; called by muse, mutect2
- PCDHGA6 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 20/572 reads (3%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.117); catalogued as COSV53922663; called by muse, mutect2
- PHB | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 176/432 reads (41%) | catalogued as COSV55932011; called by muse, varscan2
- PRKG1 | c.98T>C p.I33T | Missense Mutation (SNP) | VAF 15/444 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1237616278; called by muse, mutect2
- RPGRIP1L | c.2305-1G>T p.X769_splice | Splice Site (SNP) | VAF 226/503 reads (45%) | catalogued as CS073524, COSV50913586; called by muse, mutect2, varscan2
- RTTN | c.3373G>A p.A1125T | Missense Mutation (SNP) | VAF 335/593 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs183531175; called by muse, mutect2, varscan2
- SCUBE2 | c.1625G>T p.R542L | Missense Mutation (SNP) | VAF 168/667 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.23); catalogued as COSV58543964; called by mutect2, varscan2
- SEMA3F | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs372829300, COSV50029313; called by muse, mutect2, varscan2
- SNTG1 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 504/4236 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs769991462, COSV52435349; called by muse, mutect2, varscan2
- STAT5A | c.601del p.E201Rfs*52 | Frame Shift Del (DEL) | VAF 122/274 reads (45%) | catalogued as COSV100604590; called by mutect2, varscan2
- STK36 | c.3173C>T p.S1058F | Missense Mutation (SNP) | VAF 67/470 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV55325498; called by muse, mutect2, varscan2
- TLR3 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 303/349 reads (87%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs775850017; called by muse, mutect2, varscan2
- USP2 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 46/855 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1189353019; called by muse, mutect2
- C11orf52 | c.166del p.V56Cfs*37 | Frame Shift Del (DEL) | VAF 149/505 reads (30%) | called by mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 32/968 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CD163L1 | c.4100T>C p.I1367T | Missense Mutation (SNP) | VAF 87/518 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- DCDC1 | c.3484C>T p.H1162Y (on ENST00000597505 / NM_001367979.1; = p.H269Y on NM_020869.3) | Missense Mutation (SNP) | VAF 292/1023 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DPY19L4 | c.1172C>G p.T391S | Missense Mutation (SNP) | VAF 146/1812 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2
- EDF1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 74/352 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FBXO8 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 165/939 reads (18%) | called by muse, mutect2, varscan2
- FGFR4 | c.1973C>T p.P658L | Missense Mutation (SNP) | VAF 161/357 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FREM2 | c.4538_4544dup p.N1516Wfs*3 | Frame Shift Ins (INS) | VAF 175/774 reads (23%) | called by mutect2, varscan2
- GFPT2 | c.497C>G p.T166R | Missense Mutation (SNP) | VAF 80/379 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KIAA1109 | c.10381G>C p.D3461H | Missense Mutation (SNP) | VAF 22/918 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KIAA1210 | c.2246C>G p.T749R | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); called by muse, mutect2
- KRCC1 | c.46dup p.E16Gfs*5 | Frame Shift Ins (INS) | VAF 278/924 reads (30%) | called by mutect2, varscan2
- MXRA5 | c.971A>G p.D324G | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYNN | c.1647A>C p.L549F | Missense Mutation (SNP) | VAF 159/1704 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- NKTR | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 317/823 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- OBSCN | c.5311G>C p.G1771R | Missense Mutation (SNP) | VAF 132/244 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- OR2T2 | c.722C>G p.T241R | Missense Mutation (SNP) | VAF 209/668 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OR7G3 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH8 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 32/464 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); called by muse, mutect2
- PCDHB16 | c.1220G>C p.R407T | Missense Mutation (SNP) | VAF 121/304 reads (40%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PIEZO2 | c.6749T>G p.L2250R | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- RELN | c.3937T>C p.F1313L | Missense Mutation (SNP) | VAF 44/982 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.021); called by muse, mutect2
- SLC3A1 | c.430+2T>C p.X144_splice | Splice Site (SNP) | VAF 50/424 reads (12%) | called by muse, mutect2, varscan2
- TAF1A | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 410/784 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TAOK1 | c.2426T>G p.L809R | Missense Mutation (SNP) | VAF 98/480 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TRABD2A | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 79/695 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- USPL1 | c.3096A>C p.K1032N | Missense Mutation (SNP) | VAF 185/822 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- ZAR1L | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 226/936 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.231); called by muse, varscan2
- ZFR | c.2651C>T p.S884L | Missense Mutation (SNP) | VAF 286/703 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- ZNF585B | c.1436C>G p.S479* | Nonsense Mutation (SNP) | VAF 210/499 reads (42%) | called by muse, mutect2, varscan2
- ZNF607 | c.731A>T p.Q244L | Missense Mutation (SNP) | VAF 58/733 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2
- ATAD2B | c.264A>C p.P88= | Silent (SNP) | VAF 242/1019 reads (24%) | called by muse, mutect2, varscan2
- BAIAP2L2 | c.639G>A p.V213= | Silent (SNP) | VAF 11/235 reads (5%) | catalogued as rs1424521857; called by muse, mutect2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 12/338 reads (4%) | catalogued as rs1167537044; called by muse, mutect2
- CROCC2 | c.3273G>C p.L1091= | Silent (SNP) | VAF 17/418 reads (4%) | called by muse, mutect2
- GTF2IRD1 | c.1017C>T p.D339= | Silent (SNP) | VAF 100/534 reads (19%) | catalogued as rs782102271; called by muse, mutect2, varscan2
- KMT2A | c.336C>T p.F112= | Silent (SNP) | VAF 23/438 reads (5%) | called by muse, mutect2
- QDPR | c.490C>T p.L164= | Silent (SNP) | VAF 42/639 reads (7%) | called by muse, mutect2
- RHOBTB1 | c.474G>A p.P158= | Silent (SNP) | VAF 40/488 reads (8%) | catalogued as rs147434029; called by muse, mutect2
- SENP1 | c.1140T>C p.H380= | Silent (SNP) | VAF 50/648 reads (8%) | called by muse, mutect2
- SORL1 | c.5997C>A p.G1999= | Silent (SNP) | VAF 224/879 reads (25%) | catalogued as rs775646236, COSV99494923; called by muse, mutect2, varscan2
- SYT8 | c.417G>A p.R139= | Silent (SNP) | VAF 29/572 reads (5%) | called by muse, mutect2
- USP25 | c.57G>A p.T19= | Silent (SNP) | VAF 371/825 reads (45%) | catalogued as COSV53480646; called by muse, mutect2, varscan2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 6/78 reads (8%) | catalogued as rs1262556378; called by muse, mutect2
- AC093512.2 | c.*888+45G>A | Intron (SNP) | VAF 143/353 reads (41%) | called by muse, mutect2, varscan2
- AKT3 | c.*5520T>G | 3'UTR (SNP) | VAF 218/428 reads (51%) | called by muse, mutect2, varscan2
- ARHGAP27 | c.1843-27C>T | Intron (SNP) | VAF 50/110 reads (45%) | catalogued as rs371091359; called by muse, mutect2, varscan2
- CHGB | c.*68G>A | 3'UTR (SNP) | VAF 18/348 reads (5%) | called by muse, mutect2
- CPSF7 | c.-59C>A | 5'UTR (SNP) | VAF 20/54 reads (37%) | called by muse, varscan2
- DOLPP1 | c.*42A>G | 3'UTR (SNP) | VAF 171/217 reads (79%) | catalogued as rs1253212583; called by muse, mutect2, varscan2
- FKBP15 | c.*3146C>T | 3'UTR (SNP) | VAF 56/290 reads (19%) | catalogued as rs754942353; called by muse, mutect2, varscan2
- IGFBP1 | c.*27G>A | 3'UTR (SNP) | VAF 137/455 reads (30%) | catalogued as rs368331647, COSV99298749; called by muse, mutect2, varscan2
- TAF10 | c.*1488A>G | 3'UTR (SNP) | VAF 67/237 reads (28%) | called by muse, mutect2, varscan2
- TAPBP | c.-19C>G | 5'UTR (SNP) | VAF 12/308 reads (4%) | catalogued as rs200436656; called by muse, mutect2
- VIT | c.487+59_487+64dup | Intron (INS) | VAF 186/795 reads (23%) | called by mutect2, varscan2
